Somatic mutation profile of tumor specimen HCM-CSHL-0238-C18-01B (aliquot HCM-CSHL-0238-C18-01B-01D-A78L-36) from HCMI case HCM-CSHL-0238-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 71.8 years (26,209 days).
Specimen HCM-CSHL-0238-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fdd00de-2e46-4b90-9149-5ed8f96386b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0238-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0238-C18-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30200618-6324-48f9-bd6c-69647216ef24

The open-access MAF lists 168 somatic variants for this specimen: 114 protein-altering or splice-affecting, 41 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 41, Nonsense Mutation 9, Frame Shift Del 5, Splice Region 4, Intron 4, RNA 4, 3'UTR 2, 5'UTR 2, 5'Flank 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 161/352 reads (46%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 233/617 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1382G>A p.R461Q (on ENST00000404938 / NM_001163941.2; = p.R16Q on NM_178559.6) | Missense Mutation (SNP) | VAF 351/766 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs201067658; called by muse, mutect2, varscan2
- ABCE1 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV56847690; called by muse, mutect2, varscan2
- ACTN2 | c.2552G>A p.R851H | Missense Mutation (SNP) | VAF 94/469 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs201335965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BPIFB1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 251/535 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs200607499, COSV53604972; called by muse, mutect2, varscan2
- CALCR | c.613C>A p.L205I (on ENST00000649521 / NM_001164737.2; = p.L189I on NM_001742.4) | Missense Mutation (SNP) | VAF 64/668 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.373); catalogued as COSV64012496; called by muse, mutect2, varscan2
- CCDC138 | c.817G>C p.D273H | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs754140438; called by muse, mutect2, varscan2
- CCDC180 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as rs755611545; called by muse, mutect2, varscan2
- CDK14 | c.430G>A p.G144R (on ENST00000380050 / NM_001287135.2; = p.G126R on NM_012395.3) | Missense Mutation (SNP) | VAF 156/350 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56043685; called by muse, mutect2, varscan2
- CTSG | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 53/158 reads (34%) | catalogued as rs752353482, COSV99361305; called by muse, mutect2, varscan2
- DPP6 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV66743236; called by muse, mutect2, varscan2
- EHD3 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.056); catalogued as rs767841259; called by muse, mutect2, varscan2
- FAM20A | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 71/422 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.029); catalogued as rs1245877585; called by muse, mutect2, varscan2
- FBXL7 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 126/371 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.589); catalogued as rs1311959635, COSV61654808; called by muse, mutect2, varscan2
- FCER2 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.353); catalogued as rs201945831, COSV60915949; called by muse, mutect2, varscan2
- FCRLA | c.164C>T p.T55M (on ENST00000367959; = p.T32M on NM_032738.4) | Missense Mutation (SNP) | VAF 95/549 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs753826864, COSV52686120; called by muse, mutect2, varscan2
- FFAR3 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 95/694 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs755812436, COSV59908994; called by muse, mutect2, varscan2
- FREM2 | c.4439C>T p.T1480M | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs773471950, COSV54827280; called by muse, mutect2, varscan2
- FRG2 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 37/321 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.988); catalogued as rs1158149554, COSV66459783; called by muse, varscan2
- HDAC9 | c.1070C>T p.T357M | Missense Mutation (SNP) | VAF 131/385 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs370076387; called by muse, mutect2, varscan2
- HDX | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 255/283 reads (90%) | catalogued as rs1233675238, COSV52977081; called by muse, mutect2, varscan2
- HECTD4 | c.12094C>A p.Q4032K | Missense Mutation (SNP) | VAF 157/356 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as rs781129768; called by muse, mutect2, varscan2
- HECW1 | c.3458G>A p.R1153Q | Missense Mutation (SNP) | VAF 74/426 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs201521619, COSV67837133; called by muse, mutect2, varscan2
- HIP1R | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs773294717, COSV53440381; called by muse, mutect2, varscan2
- ITFG2 | c.96G>T p.T32= | Splice Region (SNP) | VAF 25/116 reads (22%) | catalogued as rs779988252; called by muse, mutect2, varscan2
- KHDRBS2 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 152/370 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs17853264, COSV55456305; called by muse, mutect2, varscan2
- KLHL30 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 99/167 reads (59%) | SIFT tolerated (0.51); PolyPhen benign (0.37); catalogued as rs1264620780; called by muse, mutect2, varscan2
- LAMC3 | c.3508G>A p.A1170T | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as rs200194697, COSV62655252; called by muse, mutect2, varscan2
- LCT | c.908-7C>G | Splice Region (SNP) | VAF 93/419 reads (22%) | catalogued as COSV99929315; called by muse, mutect2, varscan2
- LILRA1 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as rs771954481, COSV99251925; called by muse, mutect2
- LRP1B | c.12878G>T p.C4293F | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67269295; called by muse, mutect2, varscan2
- MGAM | c.4015G>A p.V1339I | Missense Mutation (SNP) | VAF 60/497 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.552); catalogued as rs745975997, COSV72075184; called by muse, mutect2, varscan2
- MVK | c.836T>A p.L279Q | Missense Mutation (SNP) | VAF 96/520 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM128661; called by muse, mutect2, varscan2
- NEUROD6 | c.240G>T p.R80S | Missense Mutation (SNP) | VAF 191/625 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as COSV51769940, COSV51773190; called by muse, mutect2, varscan2
- NLRP5 | c.1933G>A p.V645I | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as rs369519846, COSV66762308; called by muse, mutect2, varscan2
- NUMA1 | c.6289G>A p.A2097T | Missense Mutation (SNP) | VAF 108/131 reads (82%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs371005806; called by muse, mutect2, varscan2
- PCDH10 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV52105832; called by muse, mutect2, varscan2
- PCDHGB6 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 77/235 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1477022032, COSV53961691; called by muse, mutect2, varscan2
- PDZD4 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 242/263 reads (92%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs782409938, COSV51246022; called by muse, mutect2, varscan2
- PRKAR1B | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 41/311 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs748743633; called by muse, mutect2, varscan2
- PRR23A | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 110/249 reads (44%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as COSV101270282, COSV67213484; called by muse, mutect2, varscan2
- RAB35 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 164/429 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs895224371; called by muse, mutect2, varscan2
- RBFOX1 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 37/141 reads (26%) | catalogued as CM157820, COSV60959842; called by muse, mutect2, varscan2
- RBL2 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 143/380 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV50872871; called by muse, mutect2, varscan2
- RBMXL3 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 366/410 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.492); catalogued as COSV57747518; called by muse, mutect2, varscan2
- RYR2 | c.5588C>T p.T1863M | Missense Mutation (SNP) | VAF 103/129 reads (80%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs770863319, COSV63724318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC38A4 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 47/339 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs759965383; called by muse, mutect2, varscan2
- SLC4A3 | c.1462-8G>A | Splice Region (SNP) | VAF 30/192 reads (16%) | catalogued as rs757584414; called by muse, mutect2, varscan2
- SOS2 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1364027643, COSV53567356; called by muse, mutect2, varscan2
- SOX30 | c.1982G>T p.G661V (on ENST00000265007 / NM_178424.2; = p.V497L on NM_007017.2) | Missense Mutation (SNP) | VAF 86/309 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs771440810; called by muse, mutect2, varscan2
- SYT16 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs758851790, COSV70858745; called by muse, mutect2, varscan2
- TECTA | c.4207G>A p.V1403M | Missense Mutation (SNP) | VAF 192/245 reads (78%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs200563210, COSV50754454; called by muse, mutect2, varscan2
- TEKT4 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1352998128, COSV54623712; called by muse, mutect2, varscan2
- TEX9 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs775480026, COSV61878648; called by muse, mutect2, varscan2
- TMEM151A | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs752400796, COSV59173625; called by muse, mutect2, varscan2
- TMPRSS15 | c.2999G>A p.R1000H | Missense Mutation (SNP) | VAF 442/612 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as rs192022515, COSV53040788; called by muse, mutect2, varscan2
- TNRC6C | c.2755G>A p.A919T | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs978647209, COSV56948343; called by muse, mutect2, varscan2
- TSGA10IP | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs759743147; called by muse, mutect2, varscan2
- ZER1 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs754228946; called by muse, mutect2, varscan2
- ZFC3H1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 173/400 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs1196788792; called by muse, mutect2, varscan2
- ZMIZ2 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs753507016; called by muse, mutect2, varscan2
- ZNF175 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 172/300 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs772936588, COSV51798930; called by muse, mutect2, varscan2
- ZNF497 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs527968162; called by muse, mutect2, varscan2
- ZNF536 | c.3686C>T p.P1229L | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs371124100; called by muse, mutect2, varscan2
- ZNF585A | c.1918G>A p.G640R (on ENST00000292841 / NM_001288800.2; = p.G585R on NM_152655.3) | Missense Mutation (SNP) | VAF 143/233 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs189237393; called by muse, mutect2, varscan2
- ABCA9 | c.3436-1G>T p.X1146_splice | Splice Site (SNP) | VAF 22/166 reads (13%) | called by muse, mutect2, varscan2
- ABCC11 | c.1653C>A p.S551R | Missense Mutation (SNP) | VAF 162/364 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMER1 | c.1169del p.L390* | Frame Shift Del (DEL) | VAF 158/256 reads (62%) | called by mutect2, pindel, varscan2
- APC | c.4546del p.I1516Yfs*7 | Frame Shift Del (DEL) | VAF 100/394 reads (25%) | called by mutect2, pindel, varscan2
- BIRC6 | c.88G>C p.A30P | Missense Mutation (SNP) | VAF 103/228 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAPRIN2 | c.2806C>T p.P936S | Missense Mutation (SNP) | VAF 243/533 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC20B | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 198/556 reads (36%) | called by muse, mutect2
- CFTR | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 126/1372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRAT | c.1576C>A p.Q526K | Missense Mutation (SNP) | VAF 108/224 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- CSMD1 | c.9697G>A p.G3233S (on ENST00000520002; = p.G3232S on NM_033225.6) | Missense Mutation (SNP) | VAF 76/353 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP4V2 | c.1380_1382delinsTT p.S461Lfs*8 | Frame Shift Del (DEL) | VAF 100/515 reads (19%) | called by pindel, varscan2*
- DDX54 | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 120/348 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAT4 | c.14351C>A p.S4784Y | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- FLG2 | c.3542A>G p.Q1181R | Missense Mutation (SNP) | VAF 143/174 reads (82%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- GIPR | c.939T>G p.I313M | Missense Mutation (SNP) | VAF 96/500 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HK3 | c.2054-6C>A | Splice Region (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- HNRNPL | c.1552_1554del p.F518del | In Frame Del (DEL) | VAF 7/19 reads (37%) | called by mutect2, varscan2
- IGHV2-26 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 104/483 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KCNC1 | c.1311C>G p.N437K | Missense Mutation (SNP) | VAF 180/248 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNH5 | c.1660G>T p.A554S | Missense Mutation (SNP) | VAF 119/458 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- KIAA1109 | c.11803A>T p.K3935* | Nonsense Mutation (SNP) | VAF 195/439 reads (44%) | called by muse, mutect2, varscan2
- LNX1 | c.2058_2061dup p.I688* (on ENST00000263925 / NM_001126328.3; = p.I592* on NM_032622.2) | Nonsense Mutation (INS) | VAF 32/132 reads (24%) | called by mutect2, pindel
- MAP6 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MC3R | c.930del p.F310Lfs*11 | Frame Shift Del (DEL) | VAF 147/1283 reads (11%) | called by mutect2, pindel, varscan2
- MOCS1 | c.905G>T p.S302I | Missense Mutation (SNP) | VAF 221/316 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NPAS4 | c.1133C>G p.A378G | Missense Mutation (SNP) | VAF 98/127 reads (77%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- NT5C1B | c.732G>T p.K244N (on ENST00000359846 / NM_001199086.2; = p.K184N on NM_033253.4) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- OCA2 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 149/316 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OGFOD3 | c.123G>T p.R41S | Missense Mutation (SNP) | VAF 92/249 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR5K1 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 97/405 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OS9 | c.1484C>G p.S495C | Missense Mutation (SNP) | VAF 59/362 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- OTOGL | c.1367C>A p.S456* (on ENST00000547103; = p.S447* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/341 reads (3%) | called by muse, mutect2
- PDE10A | c.1434C>A p.D478E | Missense Mutation (SNP) | VAF 180/270 reads (67%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PRICKLE1 | c.1979T>C p.V660A | Missense Mutation (SNP) | VAF 140/372 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTN | c.362G>A p.S121N | Missense Mutation (SNP) | VAF 270/1044 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRF | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 125/185 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- RBL2 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 139/371 reads (37%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF111 | c.2350G>T p.G784C | Missense Mutation (SNP) | VAF 16/477 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SH3RF2 | c.1529G>T p.R510L | Missense Mutation (SNP) | VAF 72/361 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- SIVA1 | c.16T>G p.C6G | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SLK | c.2008C>T p.Q670* | Nonsense Mutation (SNP) | VAF 205/287 reads (71%) | called by muse, mutect2, varscan2
- SNX20 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- TAP2 | c.2047C>A p.L683I | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TIPIN | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); called by muse, mutect2
- TRPV6 | c.254G>T p.W85L | Missense Mutation (SNP) | VAF 61/494 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TTLL3 | c.1571C>A p.S524Y | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TUB | c.1105G>A p.A369T (on ENST00000299506 / NM_177972.3; = p.A424T on NM_003320.4) | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VTCN1 | c.619_620del p.T207Hfs*21 | Frame Shift Del (DEL) | VAF 57/295 reads (19%) | called by mutect2, pindel, varscan2
- ADCYAP1R1 | c.585G>A p.S195= | Silent (SNP) | VAF 116/231 reads (50%) | catalogued as rs1184308352, COSV58446469, COSV58446644; called by muse, mutect2, varscan2
- AEBP1 | c.3000G>A p.R1000= | Silent (SNP) | VAF 11/208 reads (5%) | called by muse, mutect2
- AKAP6 | c.6195C>T p.D2065= | Silent (SNP) | VAF 47/135 reads (35%) | catalogued as rs771087787; called by muse, mutect2, varscan2
- ARL3 | c.507C>A p.G169= | Silent (SNP) | VAF 167/268 reads (62%) | catalogued as COSV53299689; called by muse, mutect2, varscan2
- CAVIN1 | c.1101C>T p.P367= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs1225721187; called by muse, mutect2, varscan2
- CCR6 | c.33T>C p.V11= | Silent (SNP) | VAF 28/43 reads (65%) | called by muse, mutect2, varscan2
- CD48 | c.448C>T p.L150= | Silent (SNP) | VAF 241/312 reads (77%) | catalogued as rs17851383; called by muse, mutect2, varscan2
- CHAF1A | c.1638C>T p.D546= | Silent (SNP) | VAF 31/151 reads (21%) | catalogued as rs1371934364, COSV56671667; called by muse, mutect2, varscan2
- CMYA5 | c.285T>A p.P95= | Silent (SNP) | VAF 103/311 reads (33%) | called by muse, mutect2, varscan2
- COL16A1 | c.1446G>A p.S482= | Silent (SNP) | VAF 93/159 reads (58%) | catalogued as rs747289524; called by muse, mutect2, varscan2
- DENND1A | c.1260G>A p.K420= | Silent (SNP) | VAF 89/273 reads (33%) | catalogued as COSV101010409; called by muse, mutect2, varscan2
- DMD | c.162C>T p.L54= | Silent (SNP) | VAF 261/327 reads (80%) | catalogued as rs904011265, CD100307, COSV55876706; ClinVar: likely benign; called by muse, mutect2, varscan2
- ERICH3 | c.3498G>A p.S1166= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as rs200380141, COSV58616297; called by muse, mutect2, varscan2
- FBN3 | c.2301C>T p.V767= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1414194461, COSV54468088; called by muse, mutect2, varscan2
- FCGBP | c.6606G>A p.A2202= | Silent (SNP) | VAF 118/1258 reads (9%) | catalogued as rs1271821192, COSV99661121; called by muse, mutect2
- GATAD1 | c.280C>A p.R94= | Silent (SNP) | VAF 145/905 reads (16%) | called by muse, mutect2, varscan2
- H2BC12 | c.252C>T p.Y84= | Silent (SNP) | VAF 366/519 reads (71%) | catalogued as rs1475848743; called by muse, mutect2, varscan2
- HAS1 | c.1638C>A p.G546= | Silent (SNP) | VAF 26/95 reads (27%) | called by muse, mutect2, varscan2
- ILF3 | c.795G>A p.P265= | Silent (SNP) | VAF 172/294 reads (59%) | catalogued as rs759971222, COSV51561817; called by muse, mutect2, varscan2
- IRS1 | c.2163C>T p.S721= | Silent (SNP) | VAF 174/363 reads (48%) | catalogued as rs753351880; called by muse, mutect2, varscan2
- KDM4D | c.699C>A p.G233= | Silent (SNP) | VAF 103/380 reads (27%) | called by muse, mutect2, varscan2
- MTA1 | c.1251C>T p.C417= | Silent (SNP) | VAF 55/213 reads (26%) | catalogued as rs139203829; called by muse, mutect2, varscan2
- NFKB1 | c.2259C>G p.L753= (on ENST00000394820 / NM_001382627.1; = p.L754= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 54/259 reads (21%) | called by muse, mutect2, varscan2
- OR2T34 | c.204C>A p.I68= | Silent (SNP) | VAF 144/277 reads (52%) | called by muse, mutect2, varscan2
- PLAG1 | c.528G>A p.S176= | Silent (SNP) | VAF 145/617 reads (24%) | catalogued as rs374803048; called by muse, mutect2, varscan2
- PLPP7 | c.312G>A p.A104= | Silent (SNP) | VAF 59/108 reads (55%) | catalogued as rs371251864; called by muse, mutect2, varscan2
- PLXNB3 | c.1731C>T p.H577= | Silent (SNP) | VAF 92/238 reads (39%) | catalogued as rs782548296, COSV62800826; called by muse, mutect2, varscan2
- PRSS1 | c.360C>T p.N120= | Silent (SNP) | VAF 412/689 reads (60%) | catalogued as rs606231348; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SERPINE3 | c.786G>T p.L262= | Silent (SNP) | VAF 325/577 reads (56%) | called by muse, mutect2, varscan2
- SOX3 | c.165T>A p.A55= | Silent (SNP) | VAF 43/51 reads (84%) | called by muse, mutect2, varscan2
- SPANXN2 | c.507A>G p.S169= | Silent (SNP) | VAF 154/402 reads (38%) | called by muse, varscan2
- SSH3 | c.1050G>T p.L350= | Silent (SNP) | VAF 107/221 reads (48%) | called by muse, mutect2, varscan2
- TES | c.285G>A p.T95= | Silent (SNP) | VAF 353/601 reads (59%) | catalogued as rs756663029, COSV64041709; called by muse, mutect2, varscan2
- TMEM132D | c.171C>T p.D57= | Silent (SNP) | VAF 153/432 reads (35%) | catalogued as rs200983727; called by muse, mutect2, varscan2
- TMEM266 | c.801G>A p.A267= | Silent (SNP) | VAF 71/134 reads (53%) | called by muse, mutect2, varscan2
- TRIM71 | c.567G>A p.S189= | Silent (SNP) | VAF 38/127 reads (30%) | called by muse, mutect2, varscan2
- TUBGCP6 | c.3210G>A p.V1070= | Silent (SNP) | VAF 44/199 reads (22%) | called by muse, mutect2, varscan2
- UGT3A2 | c.1149G>T p.V383= | Silent (SNP) | VAF 56/175 reads (32%) | called by muse, mutect2, varscan2
- ZFR2 | c.846C>T p.G282= | Silent (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- ZNF229 | c.447G>A p.P149= | Silent (SNP) | VAF 91/223 reads (41%) | catalogued as rs190811456; called by muse, mutect2, varscan2
- ZNF783 | c.435C>T p.F145= | Silent (SNP) | VAF 75/472 reads (16%) | catalogued as rs368656431; called by muse, mutect2, varscan2
- A2M | c.4409-17dup | Intron (INS) | VAF 135/394 reads (34%) | catalogued as rs749161826; called by mutect2, varscan2
- AC093791.1 | n.471A>T | RNA (SNP) | VAF 92/381 reads (24%) | called by muse, mutect2, varscan2
- AP003062.1 | n.878G>T | RNA (SNP) | VAF 178/849 reads (21%) | called by muse, varscan2
- DCAF17 | c.*2505C>A | 3'UTR (SNP) | VAF 64/319 reads (20%) | called by muse, mutect2, varscan2
- GMFB | c.-41G>A | 5'UTR (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- HNRNPA3P1 | n.415G>C | RNA (SNP) | VAF 200/313 reads (64%) | called by muse, varscan2
- MLF2 | c.399+14C>T | Intron (SNP) | VAF 51/135 reads (38%) | called by muse, mutect2, varscan2
- PLBD2 | chr12:113358580 del G | 5'Flank (DEL) | VAF 78/232 reads (34%) | catalogued as rs771064415; called by mutect2, pindel, varscan2
- SQSTM1 | c.-2C>G | 5'UTR (SNP) | VAF 30/78 reads (38%) | catalogued as COSV100657618, COSV62435005; called by muse, mutect2, varscan2
- TTLL9 | c.*71G>A | 3'UTR (SNP) | VAF 190/546 reads (35%) | catalogued as rs774430370; called by muse, mutect2, varscan2
- UTS2B | c.334+1695A>G | Intron (SNP) | VAF 67/372 reads (18%) | called by muse, mutect2, varscan2
- WASF4P | n.1234C>T | RNA (SNP) | VAF 49/57 reads (86%) | called by muse, mutect2, varscan2
- ZNF829 | c.-85+71C>A | Intron (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
